Somatic mutation profile of tumor specimen 0DVBVR from CCDI case PBCLWK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 16.6 years (6,064 days).
Specimen 0DVBVR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efc53ea1-6d5c-4b86-8c1a-f05648ae1317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVBVE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08f97aed-4617-4951-842c-9f32adc9f5bc

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 3, Intron 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 231/624 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, varscan2
- CTNNB1 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 265/592 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, varscan2
- ITPR1 | c.7849G>T p.E2617* (on ENST00000354582; = p.E2562* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 184/474 reads (39%) | catalogued as COSV56980760; called by muse, varscan2
- MED13 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 224/494 reads (45%) | catalogued as COSV67267261; called by muse, varscan2
- PLEC | c.11839G>T p.V3947L (on ENST00000322810 / NM_201380.4; = p.V3837L on NM_000445.5) | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV59638641; called by muse, varscan2
- PNMA5 | c.1131C>A p.S377R | Missense Mutation (SNP) | VAF 178/216 reads (82%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV62625483; called by muse, varscan2
- PTPRC | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 247/632 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781335157, COSV100723180; called by muse, varscan2
- ROR2 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 202/490 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs752552518; called by muse, varscan2
- USP26 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 238/274 reads (87%) | catalogued as COSV63707969; called by muse, varscan2
- ZNF335 | c.1832C>G p.T611R | Missense Mutation (SNP) | VAF 160/380 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59815954; called by muse, varscan2
- CPXCR1 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 168/214 reads (79%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, varscan2
- DACH2 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 135/157 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FAM117B | c.1736C>G p.P579R | Missense Mutation (SNP) | VAF 192/477 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); called by muse, varscan2
- HHIPL1 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HSF5 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRPPRC | c.2617C>G p.L873V | Missense Mutation (SNP) | VAF 122/326 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); called by muse, varscan2
- PDE3A | c.2664C>G p.N888K | Missense Mutation (SNP) | VAF 230/599 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, varscan2
- SCN1A | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 232/544 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZGRF1 | c.2084A>G p.Q695R | Missense Mutation (SNP) | VAF 196/506 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, varscan2
- DLGAP1 | c.486C>T p.S162= | Silent (SNP) | VAF 85/200 reads (43%) | called by muse, varscan2
- FBH1 | c.2097G>A p.T699= (on ENST00000362091 / NM_178150.3; = p.T750= on NM_032807.4) | Silent (SNP) | VAF 87/202 reads (43%) | catalogued as rs761722840; called by muse, varscan2
- FGF23 | c.573C>T p.N191= | Silent (SNP) | VAF 112/248 reads (45%) | catalogued as rs886042161; ClinVar: uncertain significance; called by muse, varscan2
- OR10K2 | c.663C>T p.I221= | Silent (SNP) | VAF 143/378 reads (38%) | called by muse, varscan2
- SHROOM4 | c.2886G>T p.L962= | Silent (SNP) | VAF 254/308 reads (82%) | called by muse, varscan2
- WAC | c.1593T>G p.T531= | Silent (SNP) | VAF 172/439 reads (39%) | called by muse, varscan2
- DCHS2 | n.4376C>G | RNA (SNP) | VAF 154/344 reads (45%) | called by muse, varscan2
- MUC19 | n.17968C>T | RNA (SNP) | VAF 76/178 reads (43%) | called by muse, varscan2
- NR4A3 | c.-3+903C>G | Intron (SNP) | VAF 120/313 reads (38%) | called by muse, varscan2
- PLD3 | c.245+71C>A | Intron (SNP) | VAF 40/80 reads (50%) | catalogued as rs540371105; called by muse, varscan2
- ST3GAL6 | c.336-1941A>C | Intron (SNP) | VAF 160/408 reads (39%) | called by muse, varscan2
